Surgical pathology report (de-identified scan), TCGA case TCGA-IM-A41Z, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Miami, specimen TCGA-IM-A41Z-01A (Primary Tumor).

[page 1 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]

AGE/SEX: 'F'
REG DR: [REDACTED]

Path #:

Submit

SPECIMEN ID:

- A. THYROID GLAND - TOTAL THYROID ,
- B. THYROID GLAND - RIGHT TISSUE ADHERENT TO RIGHT THYROID GLAND FS,
- C. THYROID GLAND - TISSUE AT RT INFERIOR POLE OF THYROID R/O PARATHYROID FS,
- D. LYMPH NODE - LYMPH NODE AT RT RECURRENT NERVE,
- E. LYMPH NODE - LEFT UPPER + MEDIASTINAL NODE PARATRACHEAL (VOID),
- F. MEDIASTINAL LYMPH NODE - LEFT UPPER + MEDIASTINAL NODE PARATRACHEAL,
- G. MEDIASTINAL LYMPH NODE - RIGHT UPPER + MEDIASTINAL NODE PARATRACHEAL

A. TOTAL THYROID, 14.8 GRAMS:

99% follicular variant, per TSS. W

PAPILLARY THYROID CARCINOMA, follicular variant present in both lobes, non-encapsulated.

The larger focus is 1.5 cm and is present in the right lobe; the smaller focus is 1.3 cm and is present in the left lobe. Right lobe submitted to TCGA

Lymphovascular invasion is absent.

Surgical resection margins are negative for carcinoma.

AJCC Classification (7th Edition): pT1b NO MX

ICD-O-3

Carcinoma, papillary,

Follicular variant 8340/3

Five lymph nodes, negative for tumor.

See Surgical Pathology Cancer Case Summary.

Site: thyroid, NOS C73.9 744-12.0

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently,
return the report to us by mail.

[page 2 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

PAGE 2

SPEC #: [REDACTED]

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Prior FNA site.

Non-neoplastic thyroid demonstrates lymphocytic thyroiditis, and mild hyperplastic changes.

Immunohistochemistry performed at [REDACTED] reveals the following profile in the lesional cells:

POSITIVE: Galectin 3
CK19
Cyclin D1

NEGATIVE: HBME1

Ki67 is less than 5% by proliferative index

B. RIGHT TISSUE ADHERENT TO RIGHT THYROID GLAND:

Thyroid with hyperplastic changes with attached fibroadipose tissue.

No parathyroid gland is present.

C. TISSUE AT RIGHT INFERIOR POLE OF THYROID:

Normocellular parathyroid gland, 0.5 cm.

D. LYMPH NODE AT RIGHT RECURRENT NERVE:

One lymph node, negative for carcinoma (0/1).

E. LEFT UPPER AND MEDIASTINAL NODE PARATRACHEAL:

Specimen not submitted.

F. LEFT UPPER AND MEDIASTINAL NODE PARATRACHEAL:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call
return the report to us by mail.

[page 3 of 6]
RUN DATE:

RUN TIME:

PAGE 3

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

SPEC #:

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Thirteen lymph nodes, negative for tumor (0/13).

Thymus gland, 2.0 cm with thymic hyperplasia.

G. RIGHT UPPER AND MEDIASTINAL NODE PARATRACHEAL:

Thymus with thymic hyperplasia.

One lymph node, negative for tumor (0/1).

NOTE: [REDACTED] has reviewed select slides of the thymus from parts F and G and concurs.

Surgical Pathology Cancer Case Summary:

THYROID GLAND: Resection

Procedure: Total thyroidectomy

Specimen Integrity: Intact

Specimen Size:

Right lobe: 4.5 x 2.5 x 1.0 cm

Left lobe: 2.5 x 2.0 x 1.4 cm.

Specimen Weight: 14.8 grams

Tumor Focality: Multifocal; bilateral

Dominant Tumor:

Tumor Laterality: Right lobe and Left lobe

Tumor Size: Greatest dimension: 1.5 cm

Histologic Type: Papillary carcinoma

Variant: Follicular variant

Margins: Margins uninvolved by carcinoma

Distance of invasive carcinoma to closest margin: <1mm

Tumor Capsule: None

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call
return the report to us by mail.

[page 4 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]

PAGE 4

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

SPEC #: [REDACTED]

(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Second Tumor:

Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 1.3 cm
Histologic Type: Papillary carcinoma
Variant: Follicular variant
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 1mm
Lymph-Vascular Invasion: Not identified

Pathologic Staging:

Primary Tumor (pT):
pT1b: Tumor more than 1.0 cm, but not more than 2.0 cm in greatest dimension,
limited to the thyroid

Regional Lymph Nodes (pN):

pN0: No regional lymph node metastasis
Number examined: 20
Number involved: 1

Distant Metastasis (pM): Not applicable

GROSS DESCRIPTION:

- A. Received fresh labeled "Total thyroid" is a total thyroidectomy specimen, weighing 14.8 grams. The right lobe measures 4.5 x 2.5 x 1.0 cm. The isthmus measures 1.8 x 1.0 x 0.2 cm. The left lobe measures 2.5 x 2 x 1.4 cm. The pyramidal lobe is present and measures 1.0 cm in length. The parathyroid glands are not identified grossly. The surface is inked black. The right lobe, superior pole, reveals two minute lesions, 0.2 cm each. There is a gray-tan, light brown, well-defined nodule, 1.5 x 1.2 x 1.0 cm, located less than 0.1 cm from the outer resection margin. The isthmus contains a light-brown nodule, 0.3 x 0.3 x 0.2 cm. Cut sections through the left lobe reveal a gray-white, nodular process in the superior, mid and inferior poles. These nodules measure 0.3 x 0.2 x 0.2 cm and the largest measures 1.3 x 1.0 x 0.5 cm with cystic changes. The largest nodule is located in the mid pole, less than 0.1 cm to 0.2 cm from the outer resection margin. The specimen is submitted in toto in eighteen cassettes as follows:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call
return the report to us by mail.

[page 5 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]

PAGE 5

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

SPEC #: [REDACTED]

(Continued)

GROSS DESCRIPTION: (Continued)

Cassettes 1&2: Superior aspect, right lobe
Cassettes 3&4: Mid pole, right lobe
Cassettes 5-8: Inferior pole, right lobe (largest nodule)
Cassette 9: Superior pole, left lobe
Cassettes 10-12: Mid pole, left lobe (largest nodule)
Cassettes 13-15: Inferior pole, left lobe
Cassette 16: Pyramidal lobe in toto
Cassettes 17-18: Isthmus in toto (cassette 17 with nodule)

Note: One fragment was sent to Tissue Bank.

- B. Received fresh labeled "Right tissue adherent to right thyroid gland - rule out parathyroid" is a gray-tan soft tissue fragment, 0.5 x 0.5 x 0.2 cm. The specimen is submitted in toto in one cassette for frozen section.
- C. Received fresh labeled "Tissue at right inferior pole of thyroid - rule out parathyroid" is a gray-tan soft tissue fragment, 0.5 x 0.5 x 0.1 cm. The specimen is submitted in toto in one cassette for frozen section.
- D. Received in formalin labeled "Lymph node at right recurrent nerve" is a light brown soft tissue fragment, 0.5 x 0.5 x 0.2 cm. The specimen is submitted in toto in one cassette.
- E. Specimen void.
- F. Received in formalin labeled "Left upper and mediastinal node, paratracheal" is a yellow fibroadipose thymic tissue fragment, 3.5 x 2.0 x 1.0 cm. There are eleven possible lymph nodes, up to 2.0 cm in greatest dimension. The specimen is submitted in toto in five cassettes as follows:
- Cassette 1: Five lymph nodes per cassette
Cassette 2: Four lymph nodes per cassette
Cassettes 3&4: Largest possible lymph node, bisected
Cassette 5: Adipose tissue
- G. Received in formalin labeled "Right upper and mediastinal node paratracheal" is a yellow fibroadipose thymic tissue, 3.5 x 2.0 x 0.5 cm. There are four possible lymph nodes, up to 4.0 cm in length. The specimen is submitted in toto in six cassettes as follows:
- Cassette 1: Three fragments per cassette

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call
return the report to us by mail.

[page 6 of 6]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

PAGE 6

SPEC #: [REDACTED]

(Continued)

GROSS DESCRIPTION: (Continued)

Cassettes 2-5: Largest multisectioned node
Cassette 6: Adipose tissue

OPERATING ROOM CONSULT(

- B. TISSUE ADHERENT TO RIGHT THYROID GLAND, RULE OUT PARATHYROID, FS: Thyroid tissue.
C. TISSUE AT RIGHT INFERIOR THYROID, RULE OUT PARATHYROID, FS: Parathyroid tissue.

ICD CODES:

Signed (Signature on file)

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inac
return the report to us by mail.

7/20/12

Source: NCI Genomic Data Commons file 00a17aa9-357d-41fa-8627-d00a3239b8ef (TCGA-IM-A41Z.7AAD4353-9E3F-4463-B8F3-3DB28C749829.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).